EXCEPTIONAL_RESPONDERS case ER-AD3L — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/81960646-735b-4a84-84d8-d7d67274f8a3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1955; Vital status: Alive.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Classification of tumor: metastasis; Age at diagnosis: 44.9 years (16,386 days); Year of diagnosis: 2000; AJCC pathologic stage: Stage X; Prior malignancy: no; Days to last follow up: 5,610 days (15.4 years); Days to best overall response: 4,470 days (12.2 years); Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Everolimus; Days to treatment start: 4,410 days (12.1 years).

Follow-up (1 entry)
- Days to follow up: 5,610 days (15.4 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 4,334 days (11.9 years); Days progression-free: 5,610 days (15.4 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AD3L-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-AD3L-TTM1-A-1-0-S2: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
